Somatic mutation profile of tumor specimen MP2PRT-PAPWKT-TMP1-A (aliquot MP2PRT-PAPWKT-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPWKT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,465 days).
Specimen MP2PRT-PAPWKT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fd2477e-dfd1-43ec-8723-fcc4ecf67fd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPWKT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPWKT-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae406a5e-77be-4800-b93b-e31c2712f904

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 8, Missense Mutation 7, Nonsense Mutation 2, Frame Shift Del 1, Intron 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 27/382 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PTPN11 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507509, CD041931, CM021126, CX060726, COSV100692385, COSV61005028, COSV61006397; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GAREM1 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 49/314 reads (16%) | catalogued as COSV52510369; called by muse, mutect2, varscan2
- OCA2 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200398581; called by muse, mutect2, varscan2
- PTPN7 | c.940C>T p.R314* (on ENST00000495688; = p.R353* on NM_002832.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 141/528 reads (27%) | catalogued as rs752338465, COSV100460134; called by muse, mutect2, varscan2
- TMEM131L | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 28/543 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.286); catalogued as rs1243070929; called by muse, mutect2
- DDR2 | c.1754T>C p.M585T | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- GALNT6 | c.694_695insGTGTTCG p.V232Gfs*44 | Frame Shift Ins (INS) | VAF 136/367 reads (37%) | called by mutect2, pindel, varscan2
- SCYGR6 | c.114del p.C38* | Frame Shift Del (DEL) | VAF 258/697 reads (37%) | called by mutect2, pindel, varscan2
- SLC36A2 | c.890C>A p.A297D | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.222); called by muse, mutect2
- TRDD3 | chr14:22449102 del GTAGCACTGTGACTGGGGGATACGC | Splice Site (DEL) | VAF 48/80 reads (60%) | called by mutect2, pindel, varscan2
- ZNF407 | c.3506A>G p.Q1169R | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.084); called by muse, mutect2
- ACAD8 | c.828G>A p.G276= | Silent (SNP) | VAF 14/395 reads (4%) | catalogued as rs1366978882, COSV55540201; called by muse, mutect2
- FAT4 | c.13164C>A p.S4388= | Silent (SNP) | VAF 55/403 reads (14%) | called by muse, mutect2, varscan2
- FLNC | c.4378C>A p.R1460= | Silent (SNP) | VAF 134/353 reads (38%) | called by muse, mutect2
- GRIN2B | c.3912C>T p.Y1304= | Silent (SNP) | VAF 30/410 reads (7%) | catalogued as rs1407009840; called by muse, mutect2
- MGST2 | c.345G>A p.L115= | Silent (SNP) | VAF 110/370 reads (30%) | called by muse, mutect2, varscan2
- SEZ6 | c.2904C>T p.N968= | Silent (SNP) | VAF 76/252 reads (30%) | called by muse, mutect2, varscan2
- TLR3 | c.654C>T p.H218= | Silent (SNP) | VAF 86/362 reads (24%) | catalogued as rs147883628; called by muse, mutect2, varscan2
- ZBTB7C | c.1800C>T p.A600= | Silent (SNP) | VAF 116/617 reads (19%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-886C>A | Intron (SNP) | VAF 116/258 reads (45%) | called by muse, mutect2, varscan2
